TCGA case TCGA-09-1667 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: UCSF. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/32d4d200-1fdf-44ed-b81f-1954a9c93926

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 61 years; Vital status: Alive.

Diagnoses (2)
1. Serous cystadenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 61.1 years (22,306 days); Year of diagnosis: 2004; Method of diagnosis: Surgical Resection; FIGO stage: Stage IIC; Tumor grade: G2; Prior treatment: No; Days to last follow up: 1,882 days (5.2 years).
   Pathology details: Lymphatic invasion present: No; Residual tumor measurement: No macroscopic disease; Vascular invasion present: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Days to treatment start: 7 days; Days to treatment end: 118 days; Number of cycles: 6; Treatment dose: 6 AUC; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 7 days; Days to treatment end: 118 days; Number of cycles: 6; Treatment dose: 175 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Initial disease status: Recurrent Disease; Days to treatment start: 559 days (1.5 years); Days to treatment end: 685 days (1.9 years); Number of cycles: 5; Treatment dose: 6 AUC; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Pegylated Liposomal Doxorubicin Hydrochloride; Initial disease status: Progressive Disease; Days to treatment start: 820 days (2.2 years); Days to treatment end: 1,875 days (5.1 years); Number of cycles: 20; Treatment dose: 40 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Initial disease status: Progressive Disease; Days to treatment start: 1,135 days (3.1 years); Days to treatment end: 1,135 days (3.1 years); Number of cycles: 1; Treatment dose: 6 AUC; Route of administration: Intravenous.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Palliative; Days to treatment start: 1,539 days (4.2 years); Days to treatment end: 1,552 days (4.2 years); Treatment dose: 3,000 cGy; Number of fractions: 10; Treatment anatomic sites: Locoregional Site.
2. Recurrence of diagnosis 1 (Serous cystadenocarcinoma, NOS). Age at diagnosis: 62.3 years (22,766 days); Days to diagnosis: 460 days (1.3 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 511 days (1.4 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Recurrent Disease.

Follow-up (3 entries)
- Day 460 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 460 days (1.3 years); Evidence of recurrence type: Convincing Image Source.
- Days to follow up: 1,882 days (5.2 years); Disease response: With Tumor.
- Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Evidence of recurrence type: Convincing Image Source; Timepoint: Post Initial Treatment.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-09-1667-01C: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1; Intermediate dimension: 0.7; Shortest dimension: 0.4.
  Slide TCGA-09-1667-01C-01-TS1: Section location: Top; Percent tumor cells: 83; Percent tumor nuclei: 90; Percent normal cells: 5; Percent necrosis: 5; Percent stromal cells: 7.
  Slide TCGA-09-1667-01C-01-BS1: Section location: Bottom; Percent tumor cells: 90; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 3; Percent stromal cells: 7.
- Sample TCGA-09-1667-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection; Lymphovascular invasion indicator: No.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2: Pharmaceutical therapy drug name: Taxol.
- Drug treatment 3: Therapy regimen: Progression.
- Drug treatment 4: Pharmaceutical therapy drug name: Doxil; Therapy regimen: Progression.
- Follow-up form: Treatment outcome first course: Complete Remission/Response; Tumor status: With tumor.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,882 days; disease-specific survival: no event (censored), 1,882 days; disease-free interval: event (new tumor event after initially disease-free), 460 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 460 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-09-1667-01): tumor purity 0.75, ploidy 3.69, whole-genome doublings 1 (call status: legacy_call).
